TCGA case TCGA-XY-A9T9 — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Spectrum Health. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a0be056d-792d-40a0-97c6-fbd4976820b3

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 37 years; Year of birth: 1976; Vital status: Alive.

Diagnoses (1)
1. Seminoma, NOS: ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 37.2 years (13,604 days); Year of diagnosis: 2013; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical T: T1; AJCC clinical N: NX; AJCC clinical M: M0; AJCC clinical stage: Stage IS; AJCC pathologic T: T1; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage IS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 281 days; Ajcc serum tumor markers: S1; Sites of involvement: Epididymis.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: No; Vascular invasion present: No.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 128 days; Days to treatment end: 155 days; Treatment dose: 3,600 cGy; Treatment outcome: Complete Response; Number of fractions: 20; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 210 days; Disease response: Tumor Free.
- Days to follow up: 281 days; Disease response: Tumor Free.
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -3: Lactate Dehydrogenase 221; Alpha Fetoprotein 3.1; Human Chorionic Gonadotropin 7.
- Day 11: Lactate Dehydrogenase 184; Alpha Fetoprotein 3.1; Human Chorionic Gonadotropin 1.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Undescended testis history: No.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XY-A9T9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 200 mg.
  Slide TCGA-XY-A9T9-01A-01-TS1: Section location: Top; Percent tumor cells: 89; Percent tumor nuclei: 94; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 3; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-XY-A9T9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XY-A9T9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; History hypospadias: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Postoperative treatment list: Postoperative treatment: Radiation.
- Stage record: AJCC pathologic tumor stage: IS.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves extratesticular structures: Epididymis; Testis tumor microextent: Epididymis; Intratubular germ cell neoplasm: Present; Lymphovascular invasion: No.
- Primary pathology, Histology list, Histology: Histologic diagnosis: Seminoma, NOS; Histologic diagnosis percent: 100.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 221; Pre orchi hcg: 7; Pre orchi afp: 3.1.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 184; Post orchi hcg: 1; Post orchi afp: 3.1.
- Follow-up form: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: No Measureable Tumor or Tumor Markers; New tumor event diagnosis indicator: No.
- Follow-up form, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 281 days; disease-specific survival: no event (censored), 281 days; disease-free interval: no event (censored), 281 days; progression-free interval: no event (censored), 281 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XY-A9T9-01A-11D-A434-01): tumor purity 0.37, ploidy 2.99, whole-genome doublings 1.
